Somatic mutation profile of cancer-model specimen HCM-BROD-0701-C43-85M (Adherent Cell Line, passage 9; aliquot HCM-BROD-0701-C43-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0701-C43, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 74.1 years (27,073 days).
Specimen HCM-BROD-0701-C43-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Adherent Cell Line; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 640fef03-d4ac-4f1c-9c31-689d7734ebef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0701-C43-10A (Blood Derived Normal), aliquot HCM-BROD-0701-C43-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/49b6dc2d-a703-473c-92db-df7d21d3b22b

The open-access MAF lists 204 somatic variants for this specimen: 122 protein-altering or splice-affecting, 77 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 118, Silent 77, Frame Shift Del 2, Nonsense Mutation 2, Intron 2, 3'UTR 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD28 | c.1333G>A p.A445T | Missense Mutation (SNP) | VAF 28/304 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs2276752; called by muse, mutect2
- ANPEP | c.263C>T p.T88M | Missense Mutation (SNP) | VAF 36/609 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.426); catalogued as rs569385341, COSV55591935; called by muse, mutect2
- ASB12 | c.469G>A p.E157K | Missense Mutation (SNP) | VAF 13/416 reads (3%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as COSV62857741; called by muse, mutect2
- BCOR | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 17/507 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.991); catalogued as COSV60708534; called by muse, mutect2
- BTK | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 15/243 reads (6%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as CD972098; called by muse, mutect2
- CACNA1G | c.5854G>A p.E1952K | Missense Mutation (SNP) | VAF 50/744 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs373099107; called by muse, mutect2
- CADPS2 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 8/252 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV100465351; called by muse, mutect2
- CCDC71L | c.586G>A p.V196I | Missense Mutation (SNP) | VAF 118/1081 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.833); catalogued as rs1290586753; called by muse, mutect2
- CD101 | c.968G>A p.G323E | Missense Mutation (SNP) | VAF 16/582 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.575); catalogued as COSV56720225; called by muse, mutect2
- CFAP69 | c.1331A>G p.N444S | Missense Mutation (SNP) | VAF 21/326 reads (6%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1299113796; called by muse, mutect2
- CNTNAP2 | c.3521G>C p.G1174A | Missense Mutation (SNP) | VAF 20/664 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1454096594, COSV62160674; called by muse, mutect2
- CRNN | c.980G>A p.G327E | Missense Mutation (SNP) | VAF 24/594 reads (4%) | SIFT tolerated (0.37); PolyPhen benign (0.044); catalogued as COSV55122932; called by muse, mutect2
- CRYBG3 | c.5140A>G p.M1714V | Missense Mutation (SNP) | VAF 30/408 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs781554651; called by muse, mutect2
- DIS3L | c.865A>G p.I289V (on ENST00000319212 / NM_001143688.3; = p.I206V on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 32/482 reads (7%) | SIFT tolerated (0.75); PolyPhen benign (0.007); catalogued as rs367595589; called by muse, mutect2
- DNAJA2 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 20/385 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1406981810; called by muse, mutect2
- EDAR | c.1145G>A p.G382D | Missense Mutation (SNP) | VAF 16/538 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1471093049; called by muse, mutect2
- ETV3L | c.626G>A p.G209D | Missense Mutation (SNP) | VAF 56/602 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1046755456; called by muse, mutect2
- FBLN2 | c.139G>A p.E47K | Missense Mutation (SNP) | VAF 25/1005 reads (2%) | SIFT deleterious (0.01); PolyPhen benign (0.11); catalogued as rs1224816581; called by muse, mutect2
- GANC | c.2018G>A p.R673H | Missense Mutation (SNP) | VAF 30/489 reads (6%) | PolyPhen probably damaging (1); catalogued as rs199826780; called by muse, mutect2
- GP2 | c.221G>A p.R74Q | Missense Mutation (SNP) | VAF 45/445 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs374063505, COSV56896525; called by muse, mutect2, varscan2
- H1-7 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 44/962 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.005); catalogued as COSV100622150, COSV58602196; called by muse, mutect2
- IL18RAP | c.1637C>T p.P546L | Missense Mutation (SNP) | VAF 16/554 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.182); catalogued as COSV51826196; called by muse, mutect2
- JRK | c.484G>A p.A162T | Missense Mutation (SNP) | VAF 63/565 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.45); catalogued as rs374702795; called by muse, mutect2, varscan2
- KALRN | c.7676C>T p.T2559M (on ENST00000360013 / NM_001024660.4; = p.T862M on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 31/384 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.264); catalogued as rs776663754; called by muse, mutect2
- KIF17 | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 20/478 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56117295; called by muse, mutect2
- LAMB4 | c.1844C>T p.P615L | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.109); catalogued as rs1336696238, COSV52715160; called by muse, mutect2
- LRP1B | c.9466G>A p.G3156S | Missense Mutation (SNP) | VAF 38/334 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.78); catalogued as COSV67251180; called by muse, mutect2, varscan2
- LYST | c.629C>T p.T210I | Missense Mutation (SNP) | VAF 14/406 reads (3%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.347); catalogued as COSV67714958; called by muse, mutect2
- MAP3K5 | c.2272C>T p.P758S | Missense Mutation (SNP) | VAF 13/302 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV62892806; called by muse, mutect2
- MUC16 | c.32698C>T p.P10900S | Missense Mutation (SNP) | VAF 18/404 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.027); catalogued as COSV67487944; called by muse, mutect2
- MYBBP1A | c.1901G>A p.R634Q | Missense Mutation (SNP) | VAF 45/383 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.88); catalogued as rs113084159; called by muse, mutect2, varscan2
- NDRG2 | c.474C>G p.N158K (on ENST00000298687 / NM_001354570.1; = p.N144K on NM_016250.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 31/285 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as COSV53873565; called by muse, mutect2, varscan2
- PCLO | c.14165G>T p.R4722L | Missense Mutation (SNP) | VAF 32/364 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs948339234, COSV61628998; called by muse, mutect2
- PJVK | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 16/340 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV64306950; called by muse, mutect2
- RBM28 | c.776C>T p.S259L | Missense Mutation (SNP) | VAF 21/505 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as COSV56165069; called by muse, mutect2
- RBMXL3 | c.2831G>A p.G944E | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.972); catalogued as rs1198789715, COSV57759971; called by muse, mutect2
- SLITRK4 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 22/375 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.017); catalogued as COSV100567402; called by muse, mutect2
- ST6GALNAC5 | c.427G>A p.V143I | Missense Mutation (SNP) | VAF 26/796 reads (3%) | PolyPhen probably damaging (0.999); catalogued as rs1222512954; called by muse, mutect2
- STAG3 | c.664G>A p.G222S | Missense Mutation (SNP) | VAF 20/432 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.51); catalogued as COSV57927368; called by muse, mutect2
- SYCP1 | c.2105G>A p.R702Q | Missense Mutation (SNP) | VAF 10/269 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1487912091, COSV65694293; called by muse, mutect2
- TNFAIP3 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 28/832 reads (3%) | SIFT tolerated (0.71); PolyPhen benign (0); catalogued as COSV52797898; called by muse, mutect2
- XIRP2 | c.1279G>A p.G427S (on ENST00000628543; = p.G602S on NM_152381.6) | Missense Mutation (SNP) | VAF 13/454 reads (3%) | SIFT tolerated (0.99); PolyPhen benign (0.018); catalogued as rs1421282811; called by muse, mutect2
- ZNF727 | c.1006G>A p.G336R | Missense Mutation (SNP) | VAF 18/502 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.629); catalogued as rs1183702814; called by muse, mutect2
- ABL1 | c.1438C>T p.P480S | Missense Mutation (SNP) | VAF 20/462 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.088); called by muse, mutect2
- AC099489.1 | c.7276G>A p.A2426T | Missense Mutation (SNP) | VAF 40/880 reads (5%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.691); called by muse, mutect2
- ACTR8 | c.1341_1350del p.K447Nfs*22 | Frame Shift Del (DEL) | VAF 30/346 reads (9%) | called by mutect2, pindel
- AL136295.1 | c.1565T>C p.V522A | Missense Mutation (SNP) | VAF 18/588 reads (3%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.891); called by muse, mutect2
- ALDOA | c.163A>G p.M55V (on ENST00000642816 / NM_001243177.4; = p.M1? on NM_184041.5) | Missense Mutation (SNP) | VAF 56/546 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); called by muse, mutect2
- ATP2B2 | c.2509G>A p.A837T (on ENST00000352432; = p.A803T on NM_001683.5) | Missense Mutation (SNP) | VAF 31/396 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- BAZ2B | c.5377A>G p.M1793V | Missense Mutation (SNP) | VAF 42/406 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- C19orf44 | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 12/376 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.007); called by muse, mutect2
- CACNA1B | c.1598T>C p.M533T | Missense Mutation (SNP) | VAF 44/504 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- CASK | c.2232A>C p.L744F (on ENST00000378163 / NM_001367721.1; = p.L739F on NM_003688.3) | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNQ | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 16/295 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.202); called by muse, mutect2
- CD101 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 16/589 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); called by muse, mutect2
- CD300E | c.199G>A p.E67K | Missense Mutation (SNP) | VAF 31/491 reads (6%) | SIFT tolerated (0.32); PolyPhen benign (0.036); called by muse, mutect2
- CELSR3 | c.7951G>A p.G2651S | Missense Mutation (SNP) | VAF 24/920 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- CHD5 | c.1276G>T p.G426C | Missense Mutation (SNP) | VAF 92/794 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- CHN1 | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 15/441 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- CLK3 | c.1373C>T p.S458L (on ENST00000395066 / NM_001130028.1; = p.S310L on NM_003992.4) | Missense Mutation (SNP) | VAF 16/412 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.146); called by muse, mutect2
- COL27A1 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 27/638 reads (4%) | SIFT tolerated (0.23); PolyPhen benign (0); called by muse, mutect2
- CPA4 | c.1021G>T p.A341S | Missense Mutation (SNP) | VAF 24/470 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.149); called by muse, mutect2
- CRHR2 | c.71T>A p.L24* | Nonsense Mutation (SNP) | VAF 22/708 reads (3%) | called by muse, mutect2
- DCBLD2 | c.306_319del p.E102Dfs*11 | Frame Shift Del (DEL) | VAF 65/498 reads (13%) | called by mutect2, pindel, varscan2
- DMRTC2 | c.94C>T p.P32S | Missense Mutation (SNP) | VAF 26/811 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.551); called by muse, mutect2
- DNAAF2 | c.650C>A p.P217Q | Missense Mutation (SNP) | VAF 77/723 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.912); called by muse, varscan2
- DOT1L | c.684G>C p.W228C | Missense Mutation (SNP) | VAF 68/679 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FIG4 | c.2318C>T p.S773F | Missense Mutation (SNP) | VAF 56/453 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- FLNC | c.5707G>A p.E1903K | Missense Mutation (SNP) | VAF 15/532 reads (3%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.948); called by muse, mutect2
- FOXJ1 | c.1205C>T p.A402V | Missense Mutation (SNP) | VAF 31/740 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- GJC2 | c.43G>A p.E15K | Missense Mutation (SNP) | VAF 54/468 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- GTF3C4 | c.2360G>A p.R787K | Missense Mutation (SNP) | VAF 14/385 reads (4%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.989); called by muse, mutect2
- GUCY2F | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 9/253 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- HTRA3 | c.209G>A p.C70Y | Missense Mutation (SNP) | VAF 96/973 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- IL17RD | c.1255A>G p.I419V | Missense Mutation (SNP) | VAF 46/487 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.106); called by muse, mutect2
- INPP5E | c.287T>G p.F96C | Missense Mutation (SNP) | VAF 60/905 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- IQSEC3 | c.3331G>A p.E1111K | Missense Mutation (SNP) | VAF 24/927 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- IRF2BPL | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 92/814 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- KPRP | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 22/706 reads (3%) | SIFT tolerated (0.16); PolyPhen benign (0.058); called by muse, mutect2
- LAMA3 | c.9271G>A p.E3091K (on ENST00000313654 / NM_198129.4; = p.E1482K on NM_000227.6) | Missense Mutation (SNP) | VAF 20/594 reads (3%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.46); called by muse, mutect2
- LILRB5 | c.446G>A p.G149E | Missense Mutation (SNP) | VAF 25/898 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.634); called by muse, mutect2
- MEIG1 | c.217A>G p.R73G | Missense Mutation (SNP) | VAF 38/314 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- MRPS23 | c.268C>T p.P90S | Missense Mutation (SNP) | VAF 16/489 reads (3%) | SIFT tolerated (0.63); PolyPhen benign (0.101); called by muse, mutect2
- MYOZ1 | c.838G>A p.E280K | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.721); called by muse, mutect2
- NCKAP5 | c.3170C>T p.P1057L | Missense Mutation (SNP) | VAF 53/497 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTUM | c.602C>T p.A201V | Missense Mutation (SNP) | VAF 38/616 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.058); called by muse, mutect2
- NUP62CL | c.64A>G p.T22A | Missense Mutation (SNP) | VAF 8/199 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2
- OR2A12 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 13/419 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.178); called by muse, mutect2
- OR4C15 | c.152C>T p.S51F | Missense Mutation (SNP) | VAF 16/478 reads (3%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2
- OTOA | c.1639G>A p.V547I (on ENST00000286149; = p.V533I on NM_144672.4) | Missense Mutation (SNP) | VAF 36/308 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.165); called by muse, varscan2
- PITPNC1 | c.383C>T p.A128V | Missense Mutation (SNP) | VAF 14/400 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.033); called by muse, mutect2
- PLCH1 | c.2145A>C p.K715N (on ENST00000340059 / NM_001130960.2; = p.K727N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- PLCH2 | c.3712G>A p.G1238S | Missense Mutation (SNP) | VAF 30/1168 reads (3%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2
- PPP1R3A | c.2314G>A p.A772T | Missense Mutation (SNP) | VAF 17/514 reads (3%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- PPP6R2 | c.2314C>T p.P772S (on ENST00000216061 / NM_001365836.1; = p.P745S on NM_014678.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/509 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PTCHD1 | c.1378C>T p.L460F | Missense Mutation (SNP) | VAF 14/370 reads (4%) | SIFT tolerated (0.44); PolyPhen possibly damaging (0.89); called by muse, mutect2
- PTPRZ1 | c.5140A>G p.S1714G | Missense Mutation (SNP) | VAF 26/316 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.713); called by muse, mutect2
- RALGAPA1 | c.1790C>T p.P597L | Missense Mutation (SNP) | VAF 16/512 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.046); called by muse, mutect2
- RBM19 | c.275A>T p.H92L | Missense Mutation (SNP) | VAF 45/406 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.922); called by muse, mutect2, varscan2
- RERE | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 16/348 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.71); called by muse, mutect2
- SELE | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 13/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SHFL | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 17/505 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- SLC18A3 | c.689C>T p.P230L | Missense Mutation (SNP) | VAF 78/690 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SLC25A25 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 13/472 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.114); called by muse, mutect2
- STPG3 | c.139C>T p.P47S | Missense Mutation (SNP) | VAF 16/586 reads (3%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- SYT11 | c.403C>T p.P135S | Missense Mutation (SNP) | VAF 24/534 reads (4%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2
- TEX37 | c.50A>T p.Y17F | Missense Mutation (SNP) | VAF 30/434 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TNFRSF13C | c.443C>T p.P148L | Missense Mutation (SNP) | VAF 25/648 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.031); called by muse, mutect2
- TOMM40L | c.898C>T p.H300Y | Missense Mutation (SNP) | VAF 24/538 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.236); called by muse, mutect2
- TRAV8-3 | c.10G>A p.E4K | Missense Mutation (SNP) | VAF 10/250 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2
- TRIM49B | c.1270G>T p.D424Y | Missense Mutation (SNP) | VAF 30/365 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TSHR | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 80/676 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- UBAP2 | c.3125C>T p.P1042L | Missense Mutation (SNP) | VAF 26/838 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- UTP18 | c.956T>C p.V319A | Missense Mutation (SNP) | VAF 26/500 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.005); called by muse, mutect2
- VPS13C | c.5466G>T p.Q1822H (on ENST00000644861 / NM_020821.3; = p.Q1779H on NM_017684.5) | Missense Mutation (SNP) | VAF 29/379 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.001); called by muse, mutect2
- WDR35 | c.1106A>T p.Y369F | Missense Mutation (SNP) | VAF 46/341 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZBTB39 | c.381C>A p.S127R | Missense Mutation (SNP) | VAF 51/519 reads (10%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); called by muse, mutect2, varscan2
- ZFX | c.1735C>T p.Q579* | Nonsense Mutation (SNP) | VAF 18/247 reads (7%) | called by muse, mutect2
- ZNF616 | c.635C>G p.P212R | Missense Mutation (SNP) | VAF 18/457 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- ZNF621 | c.202G>A p.E68K | Missense Mutation (SNP) | VAF 20/532 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.196); called by muse, mutect2
- ZNF658 | c.1261T>G p.F421V | Missense Mutation (SNP) | VAF 17/529 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); called by muse, mutect2
- ZNF74 | c.341C>T p.P114L | Missense Mutation (SNP) | VAF 21/511 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.272); called by muse, mutect2
- ACTC1 | c.756T>C p.I252= | Silent (SNP) | VAF 50/367 reads (14%) | catalogued as rs371940910, CM122827; called by muse, mutect2, varscan2
- AKAP17A | c.1884C>T p.A628= | Silent (SNP) | VAF 33/1284 reads (3%) | called by muse, mutect2
- ANOS1 | c.1365C>A p.V455= | Silent (SNP) | VAF 36/201 reads (18%) | called by muse, mutect2, varscan2
- ANXA6 | c.192C>T p.S64= | Silent (SNP) | VAF 14/456 reads (3%) | catalogued as COSV62905690, COSV62908553; called by muse, mutect2
- APBA1 | c.645C>T p.L215= | Silent (SNP) | VAF 34/912 reads (4%) | called by muse, mutect2
- ATP8B2 | c.69C>T p.S23= | Silent (SNP) | VAF 18/494 reads (4%) | catalogued as rs1317092252; called by muse, mutect2
- BICD2 | c.1227C>T p.A409= | Silent (SNP) | VAF 31/711 reads (4%) | catalogued as rs1420191429; called by muse, mutect2
- BSN | c.1767G>A p.Q589= | Silent (SNP) | VAF 26/894 reads (3%) | catalogued as COSV56516014; called by muse, mutect2
- CADPS2 | c.879C>T p.F293= | Silent (SNP) | VAF 8/250 reads (3%) | catalogued as rs1375845030, COSV57377270, COSV57391060; called by muse, mutect2
- CDC20B | c.228G>A p.R76= | Silent (SNP) | VAF 15/489 reads (3%) | called by muse, mutect2
- CHD5 | c.2532G>A p.L844= | Silent (SNP) | VAF 22/730 reads (3%) | called by muse, mutect2
- CPA4 | c.483G>A p.L161= | Silent (SNP) | VAF 18/488 reads (4%) | called by muse, mutect2
- CRHR2 | c.69C>T p.L23= | Silent (SNP) | VAF 21/712 reads (3%) | called by muse, mutect2
- CRNN | c.981G>A p.G327= | Silent (SNP) | VAF 23/595 reads (4%) | catalogued as COSV55121523; called by muse, mutect2
- EFCAB6 | c.2178C>T p.I726= | Silent (SNP) | VAF 18/440 reads (4%) | called by muse, mutect2
- EIF2D | c.474G>A p.T158= | Silent (SNP) | VAF 42/492 reads (9%) | catalogued as rs782060879; called by muse, mutect2
- EPPK1 | c.2493C>T p.V831= | Silent (SNP) | VAF 21/754 reads (3%) | called by muse, mutect2
- ESYT3 | c.2523A>G p.A841= | Silent (SNP) | VAF 42/436 reads (10%) | called by muse, mutect2
- FBN3 | c.990C>T p.V330= | Silent (SNP) | VAF 20/690 reads (3%) | called by muse, mutect2
- FBXO24 | c.879G>A p.K293= (on ENST00000241071 / NM_033506.3; = p.K331= on NM_012172.5) | Silent (SNP) | VAF 19/620 reads (3%) | called by muse, mutect2
- FOXP2 | c.1317C>T p.S439= | Silent (SNP) | VAF 15/406 reads (4%) | catalogued as COSV63485278; called by muse, mutect2
- GALNT17 | c.783C>T p.S261= | Silent (SNP) | VAF 16/438 reads (4%) | catalogued as rs866747641, COSV100356753, COSV61165144; called by muse, mutect2
- GJB4 | c.319C>T p.L107= | Silent (SNP) | VAF 30/788 reads (4%) | called by muse, mutect2
- GPR50 | c.876G>A p.V292= | Silent (SNP) | VAF 15/409 reads (4%) | called by muse, mutect2
- HECTD4 | c.4779C>T p.D1593= | Silent (SNP) | VAF 16/472 reads (3%) | called by muse, mutect2
- HIVEP3 | c.2715G>A p.K905= | Silent (SNP) | VAF 20/644 reads (3%) | catalogued as COSV56015487; called by muse, mutect2
- IGSF21 | c.771C>T p.L257= | Silent (SNP) | VAF 24/836 reads (3%) | called by muse, mutect2
- INSRR | c.204C>T p.F68= | Silent (SNP) | VAF 36/876 reads (4%) | catalogued as rs866021430, COSV63878014; called by muse, mutect2
- ITPR2 | c.2283C>T p.I761= | Silent (SNP) | VAF 18/665 reads (3%) | called by muse, mutect2
- LRCH2 | c.2163G>A p.K721= | Silent (SNP) | VAF 9/191 reads (5%) | called by muse, mutect2
- LYST | c.630C>T p.T210= | Silent (SNP) | VAF 14/408 reads (3%) | called by muse, mutect2
- MACF1 | c.21753C>T p.T7251= (on ENST00000372915; = p.T5296= on NM_012090.5) | Silent (SNP) | VAF 15/393 reads (4%) | called by muse, mutect2
- MAGEE1 | c.1137C>T p.S379= | Silent (SNP) | VAF 25/634 reads (4%) | catalogued as rs782440229, COSV100819505, COSV63910022; called by muse, mutect2
- MELTF | c.879C>T p.F293= | Silent (SNP) | VAF 15/453 reads (3%) | catalogued as COSV56384495; called by muse, mutect2
- MMP9 | c.1800T>C p.R600= | Silent (SNP) | VAF 80/637 reads (13%) | called by muse, mutect2, varscan2
- MROH2A | c.2421C>T p.I807= | Silent (SNP) | VAF 15/507 reads (3%) | catalogued as rs1233409409; called by muse, mutect2
- MROH2A | c.3576C>T p.H1192= | Silent (SNP) | VAF 84/634 reads (13%) | called by muse, mutect2, varscan2
- MRPL42 | c.406C>T p.L136= | Silent (SNP) | VAF 36/276 reads (13%) | catalogued as COSV62356420; called by muse, mutect2, varscan2
- MUC16 | c.21357C>A p.I7119= | Silent (SNP) | VAF 53/526 reads (10%) | called by muse, mutect2, varscan2
- NYNRIN | c.3099C>T p.S1033= | Silent (SNP) | VAF 42/796 reads (5%) | catalogued as COSV66841651; called by muse, mutect2
- OGFOD3 | c.744C>T p.S248= | Silent (SNP) | VAF 15/546 reads (3%) | catalogued as COSV57338922; called by muse, mutect2
- OR13C4 | c.279C>T p.S93= | Silent (SNP) | VAF 20/696 reads (3%) | catalogued as COSV52927014; called by muse, mutect2
- OR13C8 | c.114C>T p.I38= | Silent (SNP) | VAF 24/614 reads (4%) | called by muse, mutect2
- OR1M1 | c.480C>T p.I160= | Silent (SNP) | VAF 20/561 reads (4%) | catalogued as COSV70036703; called by muse, mutect2
- OR2T4 | c.183G>T p.V61= | Silent (SNP) | VAF 68/638 reads (11%) | called by muse, varscan2
- OR4E1 | c.651C>T p.V217= | Silent (SNP) | VAF 16/380 reads (4%) | called by muse, mutect2
- OTOP3 | c.747C>T p.S249= | Silent (SNP) | VAF 26/292 reads (9%) | catalogued as rs745563577, COSV100172890; called by muse, mutect2
- OTUD6A | c.630C>T p.I210= | Silent (SNP) | VAF 15/480 reads (3%) | catalogued as COSV57972686; called by muse, mutect2
- PANX3 | c.792A>C p.T264= | Silent (SNP) | VAF 30/575 reads (5%) | called by muse, mutect2
- PCDHGA5 | c.1803C>T p.N601= | Silent (SNP) | VAF 39/511 reads (8%) | catalogued as rs777240886, COSV53908548; called by muse, mutect2
- PDGFRA | c.1050G>A p.L350= | Silent (SNP) | VAF 38/635 reads (6%) | called by muse, mutect2
- PEG3 | c.1155G>A p.K385= | Silent (SNP) | VAF 18/446 reads (4%) | catalogued as rs1354200481; called by muse, mutect2
- PIGM | c.1155C>T p.T385= | Silent (SNP) | VAF 17/383 reads (4%) | called by muse, mutect2
- PIP5K1C | c.765G>A p.K255= | Silent (SNP) | VAF 23/787 reads (3%) | called by muse, mutect2
- PKP2 | c.597C>T p.I199= | Silent (SNP) | VAF 22/728 reads (3%) | catalogued as rs866985131, COSV50727106, COSV50728255; called by muse, mutect2
- PPP1R26 | c.165G>A p.Q55= | Silent (SNP) | VAF 23/719 reads (3%) | called by muse, mutect2
- PRRT1B | c.791G>A p.*264= | Silent (SNP) | VAF 13/401 reads (3%) | called by muse, mutect2
- RNF217 | c.1254G>A p.R418= (on ENST00000521654 / NM_001286398.2; = p.R126= on NM_152553.5) | Silent (SNP) | VAF 17/436 reads (4%) | catalogued as rs1468014626, COSV51577479; called by muse, mutect2
- SIPA1L3 | c.4407A>G p.P1469= | Silent (SNP) | VAF 32/386 reads (8%) | called by muse, mutect2
- SLC16A6 | c.327C>T p.S109= | Silent (SNP) | VAF 23/631 reads (4%) | called by muse, mutect2
- SLC16A7 | c.312C>T p.S104= | Silent (SNP) | VAF 14/459 reads (3%) | catalogued as COSV53895809; called by muse, mutect2
- SLC22A23 | c.1617G>C p.A539= | Silent (SNP) | VAF 37/378 reads (10%) | catalogued as COSV66676852; called by muse, mutect2, varscan2
- SLC22A9 | c.411G>A p.L137= | Silent (SNP) | VAF 13/324 reads (4%) | called by muse, mutect2
- SLC35F1 | c.730C>T p.L244= | Silent (SNP) | VAF 14/502 reads (3%) | called by muse, mutect2
- SPOUT1 | c.528C>T p.D176= | Silent (SNP) | VAF 25/422 reads (6%) | called by muse, mutect2
- SSTR1 | c.930C>T p.I310= | Silent (SNP) | VAF 19/694 reads (3%) | called by muse, mutect2
- ST6GALNAC5 | c.426G>A p.R142= | Silent (SNP) | VAF 26/790 reads (3%) | catalogued as COSV100602673; called by muse, mutect2
- ST8SIA2 | c.777C>T p.I259= | Silent (SNP) | VAF 24/762 reads (3%) | catalogued as rs1198993556, COSV99184414; called by muse, mutect2
- TBC1D16 | c.369C>T p.H123= | Silent (SNP) | VAF 49/892 reads (5%) | catalogued as rs1397073473; called by muse, mutect2
- TGM1 | c.1362G>C p.G454= | Silent (SNP) | VAF 75/513 reads (15%) | called by muse, mutect2, varscan2
- THAP4 | c.612C>T p.S204= | Silent (SNP) | VAF 14/546 reads (3%) | catalogued as COSV67191398; called by muse, mutect2
- TRPC4 | c.298C>T p.L100= | Silent (SNP) | VAF 40/408 reads (10%) | catalogued as rs922543589, COSV59021708; called by muse, mutect2
- TTLL10 | c.438G>A p.G146= (on ENST00000379289 / NM_001130045.2; = p.G73= on NM_153254.3) | Silent (SNP) | VAF 32/1112 reads (3%) | called by muse, mutect2
- VWA7 | c.489C>T p.L163= | Silent (SNP) | VAF 21/804 reads (3%) | catalogued as rs1048813969; called by muse, mutect2
- WNK2 | c.5619C>T p.F1873= (on ENST00000297954 / NM_001282394.1; = p.F1836= on NM_006648.3) | Silent (SNP) | VAF 38/978 reads (4%) | catalogued as rs963337286, COSV52956683; called by muse, mutect2
- ZER1 | c.1680C>T p.D560= | Silent (SNP) | VAF 22/559 reads (4%) | catalogued as rs1304649186; called by muse, mutect2
- ZNF43 | c.1833A>C p.T611= | Silent (SNP) | VAF 14/558 reads (3%) | catalogued as COSV61685665; called by muse, mutect2
- ANKRD52 | c.*1048C>T | 3'UTR (SNP) | VAF 17/581 reads (3%) | called by muse, mutect2
- CFAP99 | chr4:2459126 G>C | 5'Flank (SNP) | VAF 71/634 reads (11%) | called by muse, mutect2, varscan2
- KCNQ1 | c.1394-32469G>C | Intron (SNP) | VAF 30/275 reads (11%) | called by muse, mutect2, varscan2
- MMP24 | c.*1636T>C | 3'UTR (SNP) | VAF 57/498 reads (11%) | called by muse, mutect2, varscan2
- TRIM4 | c.919+1053T>G | Intron (SNP) | VAF 28/580 reads (5%) | called by muse, mutect2
